FM case AD8282 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Small intestine.
https://portal.gdc.cancer.gov/cases/c3ff810d-d822-40b4-870d-65ee15be91ea

Female, 49.7 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the duodenum; primary biopsied or resected from the duodenum. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
